Somatic mutation profile of tumor specimen ALCH-B3AB-TTP1-A (aliquot ALCH-B3AB-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3AB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.8 years (21,105 days).
Specimen ALCH-B3AB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 839434db-a91e-4810-a163-5094bc5c74f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3AB-NB1-A (Blood Derived Normal), aliquot ALCH-B3AB-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc3f2f49-9353-4bf1-99b0-f5e42003997a

The open-access MAF lists 633 somatic variants for this specimen: 434 protein-altering or splice-affecting, 135 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 381, Silent 135, Intron 28, Nonsense Mutation 25, 5'UTR 12, Splice Region 10, Frame Shift Del 10, RNA 10, 3'UTR 7, Splice Site 6, 5'Flank 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.493-2A>G p.X165_splice | Splice Site (SNP) | VAF 298/470 reads (63%) | catalogued as rs587781784, CS075218, COSV64297091, COSV64308401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.608-1G>A p.X203_splice | Splice Site (SNP) | VAF 101/190 reads (53%) | hotspot (GDC flag); catalogued as CS030549, COSV57315273; called by muse, mutect2, varscan2
- ACTR3C | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 105/616 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as rs1204182868; called by muse, mutect2, varscan2
- ADAM10 | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 91/434 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV53052722; called by muse, mutect2, varscan2
- ADGRL3 | c.2684C>A p.T895K (on ENST00000506720 / NM_001322402.2; = p.T827K on NM_015236.6) | Missense Mutation (SNP) | VAF 163/402 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1173250767; called by muse, mutect2, varscan2
- AGBL1 | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759700884; called by muse, mutect2, varscan2
- AMER1 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 285/368 reads (77%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.745); catalogued as COSV57656089; called by muse, mutect2, varscan2
- ANKRD26 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 125/951 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV65776021; called by muse, mutect2, varscan2
- ANKRD28 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as rs1485915115, COSV67518335; called by muse, mutect2, varscan2
- ANKRD30A | c.634G>C p.A212P (on ENST00000611781; = p.A156P on NM_052997.2) | Missense Mutation (SNP) | VAF 135/395 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs770071345; called by muse, mutect2, varscan2
- ANXA3 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); catalogued as rs1218941988; called by muse, mutect2, varscan2
- APPBP2 | c.845C>G p.S282C | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV50027436; called by muse, mutect2, varscan2
- ARL8B | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 170/287 reads (59%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV56578304; called by muse, mutect2, varscan2
- ATP1A4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 52/509 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV63626496; called by muse, mutect2, varscan2
- B3GALT2 | c.1177T>C p.Y393H | Missense Mutation (SNP) | VAF 69/421 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs941263598; called by muse, mutect2, varscan2
- BARX2 | c.146C>G p.P49R | Missense Mutation (SNP) | VAF 160/339 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs577603862; called by muse, mutect2, varscan2
- BCL11B | c.1739G>T p.G580V (on ENST00000357195 / NM_001282237.2; = p.G509V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 182/514 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.316); catalogued as COSV61738399; called by muse, mutect2, varscan2
- BICC1 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 151/217 reads (70%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV54062557; called by muse, mutect2, varscan2
- BRAP | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs752868601; called by muse, mutect2, varscan2
- C9orf131 | c.2137G>C p.E713Q | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.646); catalogued as COSV100398126; called by muse, mutect2, varscan2
- CA10 | c.135A>G p.P45= | Splice Region (SNP) | VAF 273/613 reads (45%) | catalogued as rs1371339244; called by muse, mutect2, varscan2
- CCDC148 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs768078869, COSV51759880; called by muse, mutect2, varscan2
- CDKN2AIP | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 101/338 reads (30%) | catalogued as COSV100187557, COSV56628204; called by muse, mutect2, varscan2
- CENPF | c.8768C>T p.S2923F | Missense Mutation (SNP) | VAF 139/1147 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs375747320; called by muse, mutect2, varscan2
- CEP135 | c.1140G>C p.E380D | Missense Mutation (SNP) | VAF 79/744 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV57260233; called by muse, mutect2, varscan2
- CHCHD3 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 184/528 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs200873719; called by muse, mutect2, varscan2
- CHD5 | c.5419C>T p.R1807W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs762238932; called by muse, mutect2, varscan2
- CHMP7 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as rs1305308689; called by muse, mutect2
- CNKSR2 | c.1709G>T p.R570L | Missense Mutation (SNP) | VAF 239/295 reads (81%) | SIFT tolerated (0.12); PolyPhen benign (0.416); catalogued as rs1321222847; called by muse, mutect2, varscan2
- CNTN5 | c.689G>T p.W230L | Missense Mutation (SNP) | VAF 196/416 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54279492; called by muse, mutect2, varscan2
- CNTN5 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 202/424 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54334070; called by muse, mutect2, varscan2
- CNTN6 | c.1919C>T p.S640F | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1258560035; called by muse, mutect2, varscan2
- COL3A1 | c.4363G>C p.E1455Q | Missense Mutation (SNP) | VAF 124/465 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV104394809, COSV58586318; called by muse, mutect2, varscan2
- COL5A1 | c.3971del p.G1324Dfs*164 | Frame Shift Del (DEL) | VAF 78/235 reads (33%) | catalogued as COSV65666410; called by mutect2, pindel, varscan2
- CPA4 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1040174700; called by muse, mutect2, varscan2
- CRHR2 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1249763483; called by muse, mutect2, varscan2
- CUBN | c.10742C>A p.S3581Y | Missense Mutation (SNP) | VAF 427/1169 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.769); catalogued as COSV64716441; called by muse, mutect2, varscan2
- CYP2C18 | c.788T>G p.F263C | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780495244; called by muse, mutect2, varscan2
- DCST1 | c.275T>C p.M92T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs753589138, COSV55059481; called by muse, mutect2, varscan2
- DLGAP4 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV59419693, COSV59419757; called by muse, mutect2, varscan2
- DMRT2 | c.561C>G p.F187L | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV52400721; called by muse, mutect2, varscan2
- DNAH17 | c.4831G>A p.D1611N | Missense Mutation (SNP) | VAF 115/534 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748678130; called by muse, mutect2, varscan2
- DNAH5 | c.4967C>G p.S1656C | Missense Mutation (SNP) | VAF 138/750 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV54221249; called by muse, mutect2, varscan2
- DSCAM | c.3759G>C p.R1253S | Missense Mutation (SNP) | VAF 81/402 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV68028561, COSV68031379; called by muse, mutect2, varscan2
- DST | c.8560C>G p.L2854V | Missense Mutation (SNP) | VAF 80/419 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1270821059; called by muse, mutect2, varscan2
- ECEL1 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 86/487 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs1347082384; called by muse, mutect2, varscan2
- ELP5 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 307/540 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs752568211; called by muse, mutect2, varscan2
- ERO1A | c.630-3T>C | Splice Region (SNP) | VAF 128/383 reads (33%) | catalogued as rs1303289004; called by muse, mutect2, varscan2
- FAT4 | c.8644G>C p.D2882H | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs1053305056; called by muse, mutect2, varscan2
- FBN1 | c.301A>T p.T101S | Missense Mutation (SNP) | VAF 396/625 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as CM098635; called by muse, mutect2, varscan2
- FCRLB | c.244G>C p.V82L | Missense Mutation (SNP) | VAF 97/564 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as COSV61060452; called by muse, mutect2, varscan2
- FLG | c.5255G>A p.R1752H | Missense Mutation (SNP) | VAF 199/1134 reads (18%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.747); catalogued as rs200505799, COSV64242047; called by muse, mutect2, varscan2
- FLG | c.3850G>C p.E1284Q | Missense Mutation (SNP) | VAF 204/920 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs757534632, COSV100912370; called by muse, mutect2, varscan2
- FLG | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 138/936 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64249858; called by muse, mutect2, varscan2
- FMR1NB | c.668G>C p.R223T | Missense Mutation (SNP) | VAF 190/228 reads (83%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV65073292; called by muse, mutect2, varscan2
- FOXL1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs763233943; called by muse, mutect2, varscan2
- FRMPD1 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 82/312 reads (26%) | catalogued as COSV66703356; called by muse, mutect2, varscan2
- GC | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 125/738 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1038907964, COSV56740095, COSV99909514; called by muse, mutect2, varscan2
- GID8 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV56611299; called by muse, mutect2, varscan2
- GIMAP4 | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 285/919 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.609); catalogued as rs747652320, COSV55433451; called by muse, mutect2, varscan2
- GIPR | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 155/2005 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142528936; called by muse, mutect2
- GOLGA6L10 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 550/4511 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.486); catalogued as rs1329958140; called by muse, varscan2
- GRM1 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 633/1241 reads (51%) | catalogued as rs1187384494, COSV51341139; called by muse, mutect2, varscan2
- H2AC21 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 132/615 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV58612454; called by muse, mutect2, varscan2
- H2BC3 | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs755073705; called by muse, mutect2, varscan2
- HECTD3 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 240/831 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as rs201935586; called by muse, mutect2, varscan2
- HECW2 | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV53649979; called by muse, mutect2, varscan2
- HS3ST1 | c.246del p.A83Rfs*54 | Frame Shift Del (DEL) | VAF 67/173 reads (39%) | catalogued as COSV50023441, COSV50025270; called by mutect2, pindel, varscan2
- ICAM5 | c.595C>G p.R199G | Missense Mutation (SNP) | VAF 92/391 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs1436975175; called by muse, mutect2, varscan2
- IFT74 | c.587+1G>A p.X196_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as rs1334193252, COSV66259871; called by muse, mutect2
- IGKV1-8 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 239/516 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs533499595; called by muse, mutect2, varscan2
- IGSF3 | c.2168C>T p.S723L (on ENST00000369486 / NM_001007237.3; = p.S743L on NM_001542.4) | Missense Mutation (SNP) | VAF 127/678 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs140731595; called by muse, mutect2, varscan2
- IL18RAP | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 302/664 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV51824160; called by muse, mutect2, varscan2
- ITPKC | c.641C>G p.S214* | Nonsense Mutation (SNP) | VAF 179/334 reads (54%) | catalogued as COSV54573064; called by muse, mutect2, varscan2
- KAZN | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 73/178 reads (41%) | catalogued as COSV65721017; called by muse, mutect2, varscan2
- KBTBD7 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 39/300 reads (13%) | catalogued as rs1223056533, COSV65266731; called by muse, mutect2, varscan2
- KLRG1 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56943159; called by muse, mutect2, varscan2
- LCT | c.3360C>G p.I1120M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99929747; called by muse, mutect2, varscan2
- LRP1B | c.7978G>C p.D2660H | Missense Mutation (SNP) | VAF 86/425 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67224033; called by muse, mutect2, varscan2
- LRP1B | c.6942G>A p.M2314I | Missense Mutation (SNP) | VAF 199/393 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs1260849206; called by muse, mutect2, varscan2
- LRPPRC | c.4102G>C p.E1368Q | Missense Mutation (SNP) | VAF 233/1108 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as rs766892357; called by muse, mutect2, varscan2
- LRRC40 | c.1750A>G p.I584V | Missense Mutation (SNP) | VAF 158/461 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs762138260, COSV63941541; called by muse, mutect2, varscan2
- MAGEL2 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated, low confidence (0.06); catalogued as rs1350172782; called by muse, mutect2, varscan2
- MARF1 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.279); catalogued as rs375428441; called by muse, mutect2, varscan2
- MARK1 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 181/903 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as rs1168658742; called by muse, mutect2, varscan2
- MED16 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV54122724, COSV54128983; called by muse, mutect2
- MFSD8 | c.1340C>G p.P447R | Missense Mutation (SNP) | VAF 146/531 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM091345; called by muse, mutect2, varscan2
- MIGA2 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as rs558589665; called by muse, mutect2, varscan2
- MME | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 174/964 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV64709364; called by muse, mutect2, varscan2
- MNDA | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 73/570 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.355); catalogued as COSV63741165; called by muse, mutect2, varscan2
- MPLKIP | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 325/888 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as rs554944532; called by muse, mutect2, varscan2
- NAT14 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs1363594321; called by muse, mutect2
- NAV3 | c.5294C>T p.S1765L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs761133141, COSV57068073; called by muse, mutect2, varscan2
- NIM1K | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 146/375 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58141003; called by muse, mutect2, varscan2
- NPHS1 | c.3167G>C p.G1056A | Missense Mutation (SNP) | VAF 122/789 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as rs902081715; called by muse, mutect2, varscan2
- NTRK3 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 62/174 reads (36%) | catalogued as COSV100446293; called by muse, mutect2, varscan2
- NUDT2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469831080; called by muse, mutect2, varscan2
- OR2AK2 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs987003244; called by muse, mutect2
- OR2F1 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 166/376 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs73464588, COSV67332095; called by mutect2, varscan2
- OR2T11 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 195/473 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV100424761; called by muse, mutect2, varscan2
- PATL1 | c.839G>C p.S280T | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.785); catalogued as COSV100274999; called by muse, mutect2, varscan2
- PAX8 | c.20G>C p.R7T | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.868); catalogued as rs979804694; called by muse, mutect2, varscan2
- PCDH15 | c.4867G>A p.E1623K | Missense Mutation (SNP) | VAF 121/530 reads (23%) | SIFT tolerated, low confidence (0.2); catalogued as rs1164930896; called by muse, mutect2, varscan2
- PCDHB13 | c.2252A>G p.Y751C | Missense Mutation (SNP) | VAF 210/310 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as rs562208704; called by muse, mutect2, varscan2
- PDE4A | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs758300846; called by muse, mutect2, varscan2
- PEG3 | c.4735C>T p.L1579F | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99688554; called by muse, mutect2
- PPP1R26 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV100778141; called by muse, mutect2, varscan2
- PRDM9 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 385/1097 reads (35%) | catalogued as COSV99689765; called by muse, mutect2, varscan2
- PRKN | c.95A>T p.K32M | Missense Mutation (SNP) | VAF 183/364 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as HM070043, COSV58236577; called by muse, mutect2, varscan2
- PTPRU | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs952747316; called by muse, mutect2, varscan2
- RAB3IP | c.638C>T p.T213I (on ENST00000550536 / NM_175623.4; = p.T197I on NM_022456.5) | Missense Mutation (SNP) | VAF 207/352 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775976209; called by muse, mutect2, varscan2
- RBFOX1 | c.907G>T p.G303* | Nonsense Mutation (SNP) | VAF 227/416 reads (55%) | catalogued as COSV60973145; called by muse, mutect2, varscan2
- RFX7 | c.47G>A p.R16Q (on ENST00000559447 / NM_001368074.1; = p.R113Q on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/358 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs779100721, COSV100429065; called by muse, mutect2, varscan2
- ROBO4 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 102/192 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60627592; called by muse, mutect2, varscan2
- ROS1 | c.4003G>T p.E1335* | Nonsense Mutation (SNP) | VAF 137/572 reads (24%) | catalogued as COSV63851569; called by muse, mutect2, varscan2
- SCN11A | c.3365G>T p.W1122L | Missense Mutation (SNP) | VAF 244/368 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181353; called by muse, mutect2, varscan2
- SCN3A | c.5231C>A p.P1744Q | Missense Mutation (SNP) | VAF 440/842 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99327069; called by mutect2, varscan2
- SGSM1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs905732275, COSV68509144; called by muse, mutect2
- SLC24A4 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 150/429 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV54121712; called by muse, mutect2, varscan2
- SLC30A3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 265/521 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368210448; called by muse, mutect2, varscan2
- SLC8A3 | c.2064C>G p.N688K (on ENST00000381269 / NM_183002.3; = p.N686K on NM_033262.4) | Missense Mutation (SNP) | VAF 319/762 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53688419; called by muse, mutect2, varscan2
- SORL1 | c.5995G>A p.G1999S | Missense Mutation (SNP) | VAF 143/402 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99495433; called by muse, varscan2
- SPON2 | c.713G>T p.R238M | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV52055590; called by muse, mutect2, varscan2
- SSH1 | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 20/538 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV58457614; called by muse, mutect2
- STX7 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 101/618 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs1193625974; called by muse, mutect2, varscan2
- TBC1D14 | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 187/717 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV68985694; called by muse, mutect2, varscan2
- TBC1D16 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 207/480 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs374282827; called by muse, mutect2, varscan2
- TBC1D5 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 167/550 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as rs776955617, COSV53749648, COSV53767084; called by muse, mutect2, varscan2
- TMTC4 | c.1970C>G p.S657W (on ENST00000376234 / NM_001350577.2; = p.S676W on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60892815; called by muse, varscan2
- TP53TG3D | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs1178917218; called by mutect2, varscan2
- TPRA1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 73/517 reads (14%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.94); catalogued as rs769935140; called by muse, mutect2, varscan2
- UNC79 | c.6740G>T p.R2247L (on ENST00000393151 / NM_001346218.2; = p.R2070L on NM_020818.5) | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV56381696; called by muse, mutect2, varscan2
- UNC93B1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1362872824; called by muse, varscan2
- ZCCHC7 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 430/658 reads (65%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as rs745960560; called by muse, mutect2, varscan2
- ZEB2 | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 125/291 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57957515; called by muse, mutect2, varscan2
- ZFPM1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV60320837; called by muse, mutect2, varscan2
- ZNF208 | c.3355G>T p.G1119C | Missense Mutation (SNP) | VAF 369/645 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68112543; called by muse, mutect2, varscan2
- ZNF331 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV53476184, COSV99467801; called by muse, mutect2, varscan2
- ZNF521 | c.3898G>A p.E1300K | Missense Mutation (SNP) | VAF 12/399 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64131965; called by muse, mutect2
- ZNF549 | c.1744G>C p.E582Q (on ENST00000376233 / NM_001199295.2; = p.E569Q on NM_153263.2) | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV53727799; called by muse, mutect2, varscan2
- ZNF708 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63608138; called by muse, mutect2, varscan2
- ZNF717 | c.132G>C p.R44S | Missense Mutation (SNP) | VAF 135/210 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV68864322; called by muse, mutect2, varscan2
- ZPBP | c.716T>A p.L239Q | Missense Mutation (SNP) | VAF 243/739 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV50428026, COSV50431125; called by muse, mutect2, varscan2
- ABCA13 | c.11737G>T p.V3913F | Missense Mutation (SNP) | VAF 395/1086 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ABCB11 | c.3370C>T p.Q1124* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- ABCC5 | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 96/418 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ACACA | c.7001G>C p.R2334T | Missense Mutation (SNP) | VAF 56/1369 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.71); called by muse, mutect2
- ACAP1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 119/221 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ACSF2 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ACSL4 | c.2034G>C p.W678C (on ENST00000340800 / NM_022977.2; = p.W637C on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS14 | c.1851G>T p.Q617H | Missense Mutation (SNP) | VAF 201/300 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS3 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 108/740 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ADAMTS8 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AGBL2 | c.238_240delinsT p.I80* | Frame Shift Del (DEL) | VAF 37/451 reads (8%) | called by pindel, varscan2*
- AIM2 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.158); called by muse, mutect2
- AKT3 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AL121899.2 | c.816C>G p.S272R | Missense Mutation (SNP) | VAF 263/641 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALAD | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 428/1040 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ALS2CL | c.1929G>C p.E643D | Missense Mutation (SNP) | VAF 104/677 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMN | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, varscan2
- ANGPT2 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 114/247 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ANKRD30A | c.177G>C p.K59N (on ENST00000611781; = p.K3N on NM_052997.2) | Missense Mutation (SNP) | VAF 133/355 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ANKRD30B | c.3638G>C p.G1213A | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ANKRD31 | c.2189G>A p.R730K | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ANKRD34A | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ANKRD36C | c.1789G>T p.V597F | Missense Mutation (SNP) | VAF 127/807 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ANKRD52 | c.1696C>G p.L566V | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ANO10 | c.1464G>T p.M488I | Missense Mutation (SNP) | VAF 256/703 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ARHGEF17 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ARNT | c.2184G>T p.Q728H | Missense Mutation (SNP) | VAF 190/545 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ASTN2 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 54/628 reads (9%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); called by muse, mutect2
- ASXL3 | c.5933C>T p.S1978F | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ATAD2B | c.2834C>G p.S945* | Nonsense Mutation (SNP) | VAF 94/479 reads (20%) | called by muse, mutect2, varscan2
- ATG5 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 69/397 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ATIC | c.642G>C p.Q214H | Missense Mutation (SNP) | VAF 175/688 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8B3 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 166/286 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- BAZ2B | c.439C>G p.H147D | Missense Mutation (SNP) | VAF 90/427 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- BRPF1 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 192/723 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- BRPF1 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- BRPF3 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- C1orf141 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C2CD5 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 283/428 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1I | c.6474C>A p.S2158R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, varscan2
- CAMTA1 | c.2188G>T p.A730S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CARD6 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 249/625 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBLN1 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 300/451 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CCDC158 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CD180 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 108/735 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDYL2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 207/328 reads (63%) | called by muse, mutect2, varscan2
- CELSR1 | c.5702-2A>T p.X1901_splice | Splice Site (SNP) | VAF 215/725 reads (30%) | called by muse, mutect2, varscan2
- CEP162 | c.1891G>T p.A631S | Missense Mutation (SNP) | VAF 186/958 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.027); called by mutect2, varscan2
- CEP170 | c.15_16insA p.W6Mfs*24 | Frame Shift Ins (INS) | VAF 127/367 reads (35%) | called by mutect2, pindel, varscan2
- CFAP65 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 137/599 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CGGBP1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 66/534 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CHAMP1 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CHD1L | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 99/259 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CKM | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 76/673 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- CLTCL1 | c.4261G>A p.D1421N | Missense Mutation (SNP) | VAF 87/744 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- CNTNAP2 | c.1730A>C p.K577T | Missense Mutation (SNP) | VAF 115/644 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL25A1 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 240/385 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL3A1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 151/793 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COLGALT2 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 284/820 reads (35%) | called by muse, mutect2, varscan2
- CORO7 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 281/447 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- COX7C | c.*28-4G>A | Splice Region (SNP) | VAF 30/141 reads (21%) | called by muse, mutect2, varscan2
- CPOX | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- CRIP1 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRKL | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- CROCC | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSE1L | c.2219C>G p.S740C | Missense Mutation (SNP) | VAF 89/468 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSF2RB | c.2551C>G p.L851V | Missense Mutation (SNP) | VAF 289/522 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CSMD1 | c.7187A>G p.H2396R (on ENST00000520002; = p.H2395R on NM_033225.6) | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); called by muse, mutect2
- CTAGE9 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 542/1189 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CTNND2 | c.2936A>T p.K979M | Missense Mutation (SNP) | VAF 366/998 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CUL4A | c.712G>A p.E238K (on ENST00000375440 / NM_001008895.4; = p.E138K on NM_003589.3) | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- DCDC1 | c.4969C>A p.P1657T (on ENST00000597505 / NM_001367979.1; = p.P764T on NM_020869.3) | Missense Mutation (SNP) | VAF 223/492 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DDX24 | c.2370G>T p.K790N | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.209); called by muse, varscan2
- DEPDC1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMRT1 | c.569C>A p.A190D | Missense Mutation (SNP) | VAF 216/381 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- DNAH6 | c.2734G>C p.D912H | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.134); called by muse, mutect2
- DNAH8 | c.12590T>C p.V4197A | Missense Mutation (SNP) | VAF 95/686 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- DOT1L | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EBNA1BP2 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- EFCAB2 | c.668G>C p.R223T (on ENST00000366522; = p.R87T on NM_032328.3) | Missense Mutation (SNP) | VAF 75/387 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- EMC9 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 95/580 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ERBIN | c.2318A>G p.N773S | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ERVMER34-1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 79/1134 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ESPNL | c.1783C>T p.H595Y | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EXOC4 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- EYS | c.3431C>T p.T1144I | Missense Mutation (SNP) | VAF 287/512 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAM133A | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 127/171 reads (74%) | called by muse, mutect2, varscan2
- FAM135A | c.669+1_669+5del p.X223_splice (on ENST00000370479 / NM_001351599.1; = p.X180_splice on NM_020819.4 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 12/111 reads (11%) | called by mutect2*, pindel
- FAM149B1 | c.132_133del p.K45Rfs*9 | Frame Shift Del (DEL) | VAF 95/394 reads (24%) | called by pindel, varscan2
- FAM170B | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 118/346 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM214A | c.3046G>T p.E1016* | Nonsense Mutation (SNP) | VAF 226/318 reads (71%) | called by muse, mutect2, varscan2
- FANCI | c.1448A>C p.E483A | Missense Mutation (SNP) | VAF 431/842 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- FAT3 | c.8659C>A p.P2887T | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- FER | c.1352G>T p.S451I | Missense Mutation (SNP) | VAF 189/270 reads (70%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLRT2 | c.1185C>A p.Y395* | Nonsense Mutation (SNP) | VAF 89/214 reads (42%) | called by muse, mutect2, varscan2
- FMO5 | c.1171_1183+6del p.X391_splice | Splice Site (DEL) | VAF 52/125 reads (42%) | called by mutect2, pindel, varscan2
- FOXS1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, varscan2
- FPR2 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 125/192 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSCB | c.1166C>A p.A389E | Missense Mutation (SNP) | VAF 218/551 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FUT4 | c.1128A>T p.Q376H | Missense Mutation (SNP) | VAF 196/721 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FXR1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- GABRA4 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 174/423 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GABRA4 | c.1567C>A p.R523S | Missense Mutation (SNP) | VAF 184/510 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GBP7 | c.1205C>G p.S402C | Missense Mutation (SNP) | VAF 127/1065 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GCLC | c.378G>T p.E126D (on ENST00000643939; = p.E130D on NM_001498.4) | Missense Mutation (SNP) | VAF 313/830 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- GGNBP2 | c.1067G>T p.C356F | Missense Mutation (SNP) | VAF 166/375 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLG1 | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- GLYAT | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 51/862 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.034); called by muse, mutect2
- GNRHR | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 160/1143 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- GOLGA5 | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 100/410 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GORAB | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 144/847 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- GRIK2 | c.2612G>T p.C871F | Missense Mutation (SNP) | VAF 130/532 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GRM8 | c.778G>C p.G260R | Missense Mutation (SNP) | VAF 189/560 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GSPT1 | c.1117G>A p.E373K (on ENST00000420576 / NM_001130007.2; = p.E511K on NM_002094.4) | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- GSTM1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 300/453 reads (66%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- GSX2 | c.56C>A p.A19E | Missense Mutation (SNP) | VAF 266/3361 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); called by muse, mutect2
- HAP1 | c.722A>T p.Y241F | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- HIBCH | c.18G>C p.M6I | Missense Mutation (SNP) | VAF 147/669 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIPK1 | c.1410G>A p.V470= | Splice Region (SNP) | VAF 36/160 reads (23%) | called by muse, mutect2, varscan2
- HJV | c.1237C>G p.P413A (on ENST00000336751 / NM_213653.4; = p.P300A on NM_145277.5) | Missense Mutation (SNP) | VAF 189/259 reads (73%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNF4A | c.767C>A p.P256Q | Missense Mutation (SNP) | VAF 266/580 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- HPS1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 24/806 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); called by muse, mutect2
- HUWE1 | c.758A>C p.K253T | Missense Mutation (SNP) | VAF 127/397 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- IFT88 | c.1481C>T p.A494V (on ENST00000319980 / NM_001318493.2; = p.A485V on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- IGHA2 | c.231C>A p.C77* | Nonsense Mutation (SNP) | VAF 237/474 reads (50%) | called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 188/1150 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- IGLV2-23 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 132/749 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- INSR | c.2303G>A p.G768E | Missense Mutation (SNP) | VAF 277/404 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IQCB1 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 384/1123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGB2 | c.1904T>C p.L635P (on ENST00000302347; = p.L611P on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 227/475 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ITPKC | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 153/544 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITPR2 | c.7643G>T p.R2548I | Missense Mutation (SNP) | VAF 231/356 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITSN1 | c.723A>T p.T241= | Splice Region (SNP) | VAF 63/215 reads (29%) | called by muse, mutect2, varscan2
- JPH1 | c.410T>A p.M137K | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- JPH4 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- KAZN | c.1535A>T p.E512V | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- KCNAB1 | c.792del p.C264Wfs*25 (on ENST00000490337 / NM_172160.3; = p.C253Wfs*25 on NM_003471.3) | Frame Shift Del (DEL) | VAF 185/623 reads (30%) | called by mutect2, pindel, varscan2
- KCNC1 | c.689del p.G230Afs*42 | Frame Shift Del (DEL) | VAF 130/324 reads (40%) | called by mutect2, pindel, varscan2
- KCNV1 | c.107C>A p.A36E | Missense Mutation (SNP) | VAF 182/254 reads (72%) | SIFT tolerated (0.67); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- KEAP1 | c.753del p.W252Gfs*25 | Frame Shift Del (DEL) | VAF 241/456 reads (53%) | called by mutect2, pindel, varscan2
- KIF15 | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 106/836 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIFC1 | c.1899G>A p.K633= | Splice Region (SNP) | VAF 76/279 reads (27%) | called by muse, mutect2, varscan2
- KLHL4 | c.1949G>T p.W650L | Missense Mutation (SNP) | VAF 107/145 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT77 | c.281del p.G94Afs*46 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | called by mutect2, pindel, varscan2
- KRTAP13-1 | c.12C>G p.N4K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by mutect2, varscan2
- LAMA1 | c.2893G>A p.D965N | Missense Mutation (SNP) | VAF 238/536 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- LENG1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 116/358 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- LGI4 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 79/980 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- LILRB1 | c.1855T>C p.S619P (on ENST00000427581; = p.S568P on NM_006669.6) | Missense Mutation (SNP) | VAF 256/383 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIN37 | c.241del p.D81Mfs*16 | Frame Shift Del (DEL) | VAF 47/75 reads (63%) | called by mutect2, pindel, varscan2
- LRP1B | c.13708C>A p.Q4570K | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- LRRC37A3 | c.4000A>T p.S1334C | Missense Mutation (SNP) | VAF 314/1134 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.253); called by mutect2, varscan2
- LRRC4C | c.993C>A p.N331K | Missense Mutation (SNP) | VAF 156/520 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MAGEC1 | c.2196G>T p.Q732H | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- MALRD1 | c.2809G>A p.D937N | Missense Mutation (SNP) | VAF 56/355 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP2 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- MARCHF7 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 74/479 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK2 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 109/222 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- MED1 | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 102/344 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- MEOX2 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 361/983 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- MKI67 | c.2425G>A p.V809M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, varscan2
- MLKL | c.1346G>C p.R449P | Missense Mutation (SNP) | VAF 244/350 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MXRA5 | c.5600C>T p.A1867V | Missense Mutation (SNP) | VAF 163/200 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MYT1 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 78/286 reads (27%) | called by muse, mutect2, varscan2
- NAALAD2 | c.990-4C>A | Splice Region (SNP) | VAF 57/121 reads (47%) | called by muse, mutect2, varscan2
- NEMF | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 132/796 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NLGN4X | c.2160T>A p.D720E | Missense Mutation (SNP) | VAF 248/321 reads (77%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOTCH1 | c.4490G>T p.W1497L | Missense Mutation (SNP) | VAF 293/774 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR5A1 | c.1359C>G p.I453M | Missense Mutation (SNP) | VAF 190/543 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- NRXN3 | c.1279G>A p.D427N (on ENST00000335750 / NM_001330195.2; = p.D54N on NM_004796.6) | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OACYLP | n.910T>C | Splice Region (SNP) | VAF 58/522 reads (11%) | called by muse, mutect2, varscan2
- OR13A1 | c.773C>A p.T258N | Missense Mutation (SNP) | VAF 130/320 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR4K14 | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 334/694 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR6C65 | c.858T>A p.F286L | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- OR8B12 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 99/314 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- OR8J3 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 92/397 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR9I1 | c.558G>T p.K186N | Missense Mutation (SNP) | VAF 242/542 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- PALM3 | c.604G>A p.A202T (on ENST00000340790; = p.A217T on NM_001145028.2) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PAPSS2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 156/525 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- PCDHGA7 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB2 | c.2166T>A p.D722E | Missense Mutation (SNP) | VAF 391/580 reads (67%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDCD6IP | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 228/359 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PDE4B | c.750C>T p.F250= | Splice Region (SNP) | VAF 123/402 reads (31%) | called by muse, mutect2, varscan2
- PDE4D | c.1630C>G p.Q544E (on ENST00000340635 / NM_001104631.2; = p.Q408E on NM_006203.4) | Missense Mutation (SNP) | VAF 78/597 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, varscan2
- PDHA2 | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 201/298 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF12 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- PHTF2 | c.502G>C p.E168Q (on ENST00000248550 / NM_001366089.1; = p.E130Q on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/659 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHYH | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 267/1286 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PKHD1 | c.8845G>A p.E2949K | Missense Mutation (SNP) | VAF 207/1332 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLS3 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2
- PLXDC1 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 73/448 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNLIPRP2 | c.1068+2G>A | Missense Mutation (SNP) | VAF 51/143 reads (36%) | called by muse, mutect2, varscan2
- POU3F1 | c.1038C>G p.I346M | Missense Mutation (SNP) | VAF 94/522 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R26 | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 48/405 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- PRDM10 | c.786G>T p.R262S | Missense Mutation (SNP) | VAF 89/396 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRDM10 | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 70/450 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRDM12 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 176/564 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- PRDM9 | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 154/1094 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM9 | c.1584G>T p.E528D | Missense Mutation (SNP) | VAF 419/1149 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PRELID2 | c.136G>T p.E46* (on ENST00000334744 / NM_182960.4; = p.E17* on NM_138492.6) | Nonsense Mutation (SNP) | VAF 188/296 reads (64%) | called by muse, mutect2, varscan2
- PROP1 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 188/701 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRRC2C | c.6371C>T p.S2124L (on ENST00000367742; = p.S2122L on NM_015172.4) | Missense Mutation (SNP) | VAF 101/697 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRC | c.935C>A p.T312K | Missense Mutation (SNP) | VAF 139/447 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- PTPRG | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRM | c.1761dup p.M588Yfs*5 | Frame Shift Ins (INS) | VAF 213/404 reads (53%) | called by mutect2, pindel, varscan2
- PZP | c.4090C>A p.H1364N | Missense Mutation (SNP) | VAF 269/382 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RALGAPB | c.3515A>T p.Q1172L | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RALGAPB | c.4327A>G p.R1443G | Missense Mutation (SNP) | VAF 342/719 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RAP1GAP2 | c.504C>G p.N168K | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RBM8A | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- RBMXL3 | c.1237C>A p.Q413K | Missense Mutation (SNP) | VAF 114/161 reads (71%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RCHY1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 134/322 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RETNLB | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RGS1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 230/687 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMS1 | c.2329C>A p.P777T | Missense Mutation (SNP) | VAF 96/583 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RMI1 | c.882A>T p.R294S | Missense Mutation (SNP) | VAF 143/198 reads (72%) | SIFT tolerated (0.45); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RNF157 | c.171C>A p.N57K | Missense Mutation (SNP) | VAF 133/536 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- RNF187 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 161/444 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ROBO1 | c.3146A>T p.E1049V | Missense Mutation (SNP) | VAF 216/337 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RP2 | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 81/221 reads (37%) | called by muse, varscan2
- RPP30 | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 139/411 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SACS | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 143/631 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SAMD9 | c.3101_3102del p.L1034Pfs*8 | Frame Shift Del (DEL) | VAF 219/2188 reads (10%) | called by mutect2, pindel, varscan2
- SELENOI | c.92A>C p.Y31S | Missense Mutation (SNP) | VAF 137/535 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SIM1 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 56/345 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC18B1 | c.639G>C p.M213I | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35G4 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 354/851 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- SLC36A2 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 114/390 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC39A12 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 219/669 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SLITRK1 | c.671A>T p.K224I | Missense Mutation (SNP) | VAF 110/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLITRK3 | c.1486C>A p.Q496K | Missense Mutation (SNP) | VAF 310/765 reads (41%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- SP4 | c.1301A>G p.Q434R | Missense Mutation (SNP) | VAF 147/647 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SPAG6 | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA19 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 66/510 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA31D1 | c.4702C>A p.Q1568K | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, varscan2
- SPRY4 | c.686C>G p.S229C (on ENST00000434127 / NM_001127496.3; = p.S252C on NM_030964.4) | Missense Mutation (SNP) | VAF 125/162 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SRGAP1 | c.1023G>A p.E341= | Splice Region (SNP) | VAF 66/96 reads (69%) | called by muse, mutect2, varscan2
- STARD3NL | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 56/304 reads (18%) | called by muse, mutect2, varscan2
- STK32C | c.1211A>G p.K404R | Missense Mutation (SNP) | VAF 166/370 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- TBX4 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 137/301 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TBXT | c.1279T>A p.W427R | Missense Mutation (SNP) | VAF 128/531 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCTEX1D1 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- TDRD12 | c.1887G>C p.M629I | Missense Mutation (SNP) | VAF 99/612 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TGIF1 | c.727G>C p.E243Q (on ENST00000330513 / NM_001374396.1; = p.E263Q on NM_003244.4) | Missense Mutation (SNP) | VAF 118/1540 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2
- THEM5 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 190/592 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THNSL2 | c.931G>C p.A311P | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEFF2 | c.239G>A p.C80Y | Missense Mutation (SNP) | VAF 220/532 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM126A | c.539T>G p.L180R | Missense Mutation (SNP) | VAF 153/544 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TMEM127 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 120/471 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.733); called by muse, varscan2
- TMEM39A | c.95G>C p.G32A | Missense Mutation (SNP) | VAF 114/645 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMTC2 | c.1287G>T p.M429I | Missense Mutation (SNP) | VAF 168/256 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TOMM70 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 59/437 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOP3B | c.2553G>T p.K851N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TOPAZ1 | c.3228G>T p.K1076N | Missense Mutation (SNP) | VAF 64/529 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- TRAF4 | c.764C>G p.S255C | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- TRIM32 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- TTC8 | c.252G>T p.L84F (on ENST00000338104 / NM_001288781.1; = p.L94F on NM_144596.4) | Missense Mutation (SNP) | VAF 233/1041 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TTF2 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 123/449 reads (27%) | called by muse, mutect2, varscan2
- UBA6 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- UGT3A1 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 159/1092 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- UNC5D | c.1847T>A p.F616Y | Missense Mutation (SNP) | VAF 189/367 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- UNC93A | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- USP37 | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 116/514 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- USP4 | c.2369C>G p.T790S | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- UTY | c.276C>G p.F92L | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- VWA5B1 | c.2524C>G p.Q842E | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WASHC2C | c.1865A>T p.E622V | Missense Mutation (SNP) | VAF 315/786 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR43 | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR7 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 66/96 reads (69%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.522); called by muse, mutect2
- WTIP | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 327/383 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- XIRP2 | c.2938G>T p.E980* (on ENST00000628543; = p.E1155* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 69/389 reads (18%) | called by muse, mutect2, varscan2
- XIRP2 | c.9587T>A p.F3196Y (on ENST00000628543; = p.F3371Y on NM_152381.6) | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- XPO4 | c.2965G>C p.E989Q | Missense Mutation (SNP) | VAF 195/416 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- YTHDC1 | c.1640A>G p.K547R (on ENST00000344157 / NM_001031732.4; = p.K529R on NM_133370.4) | Missense Mutation (SNP) | VAF 172/493 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZBTB7B | c.1356G>C p.Q452H (on ENST00000292176; = p.Q486H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/744 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZC3H3 | c.2175G>C p.K725N | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ZCCHC24 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by muse, mutect2
- ZFAND1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 91/312 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- ZNF292 | c.5344G>A p.E1782K | Missense Mutation (SNP) | VAF 19/581 reads (3%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.053); called by muse, mutect2
- ZNF462 | c.4919G>C p.G1640A | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF462 | c.5629G>A p.D1877N | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF574 | c.2143G>A p.V715I | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF608 | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ZNF626 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ZNF627 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 114/164 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF654 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 40/318 reads (13%) | called by muse, mutect2, varscan2
- ZNF669 | c.1386G>T p.W462C | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- ZNF714 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 146/888 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- ZNF845 | c.852A>T p.L284F | Missense Mutation (SNP) | VAF 298/444 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZNF879 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 155/277 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZZEF1 | c.8052G>C p.M2684I | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AASDH | c.2718G>C p.L906= | Silent (SNP) | VAF 60/1171 reads (5%) | called by muse, mutect2
- ADARB2 | c.1869G>C p.V623= | Silent (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- ADCY10 | c.75C>T p.V25= | Silent (SNP) | VAF 163/917 reads (18%) | catalogued as rs765649268, COSV63241682; called by muse, mutect2, varscan2
- AFG3L2 | c.1542A>G p.P514= | Silent (SNP) | VAF 270/1614 reads (17%) | called by muse, mutect2, varscan2
- AHNAK2 | c.11256C>A p.V3752= | Silent (SNP) | VAF 367/668 reads (55%) | called by muse, mutect2, varscan2
- AKAIN1 | c.9C>T p.F3= | Silent (SNP) | VAF 538/1295 reads (42%) | catalogued as rs1399743795, COSV71420250; called by muse, mutect2, varscan2
- ALMS1 | c.8457C>T p.G2819= | Silent (SNP) | VAF 101/351 reads (29%) | called by muse, mutect2, varscan2
- AMBN | c.1092G>T p.L364= | Silent (SNP) | VAF 111/250 reads (44%) | catalogued as rs1228256377; called by muse, mutect2, varscan2
- AMOTL2 | c.33C>T p.V11= | Silent (SNP) | VAF 104/676 reads (15%) | catalogued as rs546656120; called by muse, mutect2, varscan2
- ANKRD30A | c.594G>C p.A198= (on ENST00000611781; = p.A142= on NM_052997.2) | Silent (SNP) | VAF 27/226 reads (12%) | catalogued as COSV100654478; called by muse, mutect2, varscan2
- AP3M1 | c.828G>A p.V276= | Silent (SNP) | VAF 102/299 reads (34%) | called by muse, mutect2, varscan2
- AUTS2 | c.1770C>A p.I590= | Silent (SNP) | VAF 27/338 reads (8%) | called by muse, mutect2
- BCR | c.807C>G p.P269= | Silent (SNP) | VAF 190/379 reads (50%) | called by muse, mutect2, varscan2
- BICRA | c.2424G>A p.Q808= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2
- BOC | c.1707G>T p.R569= | Silent (SNP) | VAF 140/293 reads (48%) | catalogued as rs1271813466; called by muse, mutect2, varscan2
- BRPF1 | c.1413G>A p.E471= | Silent (SNP) | VAF 58/252 reads (23%) | catalogued as COSV57404047; called by muse, mutect2, varscan2
- BTNL9 | c.1293C>T p.F431= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as rs754599052; called by muse, mutect2, varscan2
- C1QTNF7 | c.393G>A p.G131= | Silent (SNP) | VAF 74/324 reads (23%) | catalogued as COSV54856721; called by muse, mutect2, varscan2
- CAPRIN1 | c.456A>T p.L152= | Silent (SNP) | VAF 446/1048 reads (43%) | catalogued as COSV58219211; called by muse, mutect2, varscan2
- CARD11 | c.2874C>T p.L958= | Silent (SNP) | VAF 21/156 reads (13%) | catalogued as COSV67801156; called by muse, mutect2, varscan2
- CELF4 | c.999A>G p.P333= | Silent (SNP) | VAF 134/294 reads (46%) | catalogued as rs1187809675; called by muse, mutect2, varscan2
- CEP89 | c.2247C>T p.P749= | Silent (SNP) | VAF 108/924 reads (12%) | called by muse, mutect2, varscan2
- CFAP54 | c.7137C>T p.F2379= | Silent (SNP) | VAF 142/580 reads (24%) | catalogued as COSV61571666; called by muse, mutect2, varscan2
- CLEC12B | c.282G>A p.Q94= | Silent (SNP) | VAF 189/645 reads (29%) | called by muse, mutect2, varscan2
- CLIP2 | c.492G>A p.L164= | Silent (SNP) | VAF 117/802 reads (15%) | catalogued as rs1554732713; called by muse, mutect2, varscan2
- CLUH | c.2220G>A p.K740= (on ENST00000435359; = p.K779= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/309 reads (5%) | called by muse, mutect2
- CNTNAP3B | c.2046G>C p.L682= | Silent (SNP) | VAF 120/407 reads (29%) | catalogued as rs1258478318; called by muse, mutect2, varscan2
- CRIM1 | c.1101C>T p.F367= | Silent (SNP) | VAF 118/635 reads (19%) | called by muse, mutect2, varscan2
- DAPK1 | c.612G>T p.G204= | Silent (SNP) | VAF 110/176 reads (63%) | called by muse, mutect2, varscan2
- DDX11 | c.1686A>G p.P562= | Silent (SNP) | VAF 392/600 reads (65%) | catalogued as rs1228823460; called by muse, mutect2, varscan2
- DGKG | c.675G>A p.L225= | Silent (SNP) | VAF 62/444 reads (14%) | catalogued as rs142983391; called by muse, mutect2, varscan2
- DICER1 | c.1602G>A p.V534= | Silent (SNP) | VAF 173/941 reads (18%) | called by muse, mutect2, varscan2
- DIS3L2 | c.2040G>T p.L680= | Silent (SNP) | VAF 71/229 reads (31%) | catalogued as rs751823544; ClinVar: likely benign; called by muse, mutect2, varscan2
- DMD | c.10857G>A p.Q3619= | Silent (SNP) | VAF 237/771 reads (31%) | called by muse, mutect2, varscan2
- DNAH7 | c.7374C>T p.F2458= | Silent (SNP) | VAF 199/846 reads (24%) | called by muse, mutect2, varscan2
- DNAJC11 | c.1413G>A p.K471= | Silent (SNP) | VAF 60/243 reads (25%) | called by muse, mutect2, varscan2
- DND1 | c.42G>A p.V14= | Silent (SNP) | VAF 145/652 reads (22%) | called by muse, mutect2, varscan2
- DNER | c.898C>T p.L300= | Silent (SNP) | VAF 133/638 reads (21%) | called by muse, mutect2, varscan2
- DSC1 | c.2256C>A p.L752= | Silent (SNP) | VAF 153/396 reads (39%) | catalogued as rs765807646, COSV57144238; called by muse, mutect2, varscan2
- ECEL1 | c.1032G>T p.L344= | Silent (SNP) | VAF 89/489 reads (18%) | catalogued as COSV100458701; called by muse, mutect2, varscan2
- EMC6 | c.57G>A p.V19= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs778357173; called by muse, mutect2, varscan2
- FAM200B | c.528G>A p.L176= | Silent (SNP) | VAF 206/439 reads (47%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1629A>T p.P543= | Silent (SNP) | VAF 153/364 reads (42%) | called by muse, mutect2, varscan2
- FRZB | c.912C>T p.S304= | Silent (SNP) | VAF 144/588 reads (24%) | called by muse, mutect2, varscan2
- GALNT2 | c.885G>T p.G295= | Silent (SNP) | VAF 153/444 reads (34%) | called by muse, varscan2
- GAS2L3 | c.123G>A p.V41= | Silent (SNP) | VAF 127/475 reads (27%) | called by muse, mutect2, varscan2
- GDPD1 | c.213A>G p.L71= | Silent (SNP) | VAF 231/507 reads (46%) | catalogued as rs1196255516; called by muse, mutect2, varscan2
- GLI3 | c.1170G>A p.Q390= | Silent (SNP) | VAF 192/1115 reads (17%) | called by muse, mutect2, varscan2
- GNA12 | c.111G>A p.R37= | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2
- GOLPH3 | c.642C>T p.I214= | Silent (SNP) | VAF 202/787 reads (26%) | called by muse, mutect2, varscan2
- HACD2 | c.441C>T p.I147= | Silent (SNP) | VAF 97/636 reads (15%) | called by muse, mutect2, varscan2
- HERC2 | c.12318C>T p.V4106= | Silent (SNP) | VAF 103/298 reads (35%) | catalogued as rs1364315840; called by muse, mutect2, varscan2
- HMX2 | c.114C>T p.V38= | Silent (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- IFNA21 | c.64C>T p.L22= | Silent (SNP) | VAF 90/270 reads (33%) | catalogued as COSV66518726; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.15G>A p.L5= | Silent (SNP) | VAF 49/376 reads (13%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.168C>A p.T56= | Silent (SNP) | VAF 145/739 reads (20%) | called by muse, mutect2, varscan2
- INKA1 | c.30T>C p.L10= | Silent (SNP) | VAF 126/210 reads (60%) | called by muse, varscan2
- INPPL1 | c.1875G>A p.R625= | Silent (SNP) | VAF 149/574 reads (26%) | called by muse, mutect2, varscan2
- KCNH3 | c.1401C>T p.G467= | Silent (SNP) | VAF 103/181 reads (57%) | called by muse, mutect2, varscan2
- KCNH7 | c.801A>G p.L267= | Silent (SNP) | VAF 84/177 reads (47%) | called by muse, mutect2, varscan2
- KCTD11 | c.459G>A p.L153= (on ENST00000333751 / NM_001363642.1; = p.L114= on NM_001002914.2) | Silent (SNP) | VAF 245/416 reads (59%) | called by muse, mutect2, varscan2
- KDM6A | c.3843C>T p.I1281= | Silent (SNP) | VAF 17/458 reads (4%) | called by muse, mutect2
- KLC3 | c.756C>G p.L252= | Silent (SNP) | VAF 45/272 reads (17%) | called by muse, mutect2, varscan2
- LAMC3 | c.2385G>A p.G795= | Silent (SNP) | VAF 178/419 reads (42%) | called by muse, mutect2, varscan2
- LRFN4 | c.985C>A p.R329= | Silent (SNP) | VAF 52/142 reads (37%) | called by muse, mutect2, varscan2
- LRP3 | c.357C>T p.L119= | Silent (SNP) | VAF 179/899 reads (20%) | catalogued as rs1394425168, COSV99472270; called by muse, mutect2, varscan2
- LRRTM4 | c.1446G>A p.Q482= | Silent (SNP) | VAF 63/370 reads (17%) | catalogued as rs1385880217; called by muse, mutect2, varscan2
- MAGEB2 | c.831G>A p.P277= | Silent (SNP) | VAF 82/241 reads (34%) | catalogued as rs760918442, COSV100975685, COSV66781073; called by muse, mutect2, varscan2
- MAGED1 | c.1344G>A p.L448= | Silent (SNP) | VAF 244/299 reads (82%) | called by muse, mutect2, varscan2
- MBD5 | c.1224A>C p.P408= | Silent (SNP) | VAF 208/923 reads (23%) | catalogued as COSV68695527; called by muse, mutect2, varscan2
- MCTP2 | c.2031C>T p.F677= | Silent (SNP) | VAF 96/442 reads (22%) | catalogued as rs775182356, COSV59144436; called by muse, mutect2, varscan2
- MPND | c.363C>T p.F121= | Silent (SNP) | VAF 139/552 reads (25%) | catalogued as rs759165167; called by muse, mutect2, varscan2
- MPO | c.582C>G p.A194= | Silent (SNP) | VAF 152/398 reads (38%) | catalogued as rs1481018192; called by muse, mutect2, varscan2
- NBEAL2 | c.3075C>T p.F1025= | Silent (SNP) | VAF 36/793 reads (5%) | catalogued as COSV52761362; called by muse, mutect2
- NEK11 | c.1872C>G p.L624= | Silent (SNP) | VAF 176/1004 reads (18%) | called by muse, mutect2, varscan2
- NOL10 | c.987G>A p.T329= | Silent (SNP) | VAF 69/425 reads (16%) | catalogued as rs1350722182; called by muse, mutect2, varscan2
- NR2F2 | c.342G>T p.T114= | Silent (SNP) | VAF 134/607 reads (22%) | called by muse, mutect2, varscan2
- NRXN3 | c.1674G>A p.V558= (on ENST00000335750 / NM_001330195.2; = p.V185= on NM_004796.6) | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as COSV59807652; called by muse, mutect2, varscan2
- OR10Q1 | c.483G>T p.L161= | Silent (SNP) | VAF 272/598 reads (45%) | called by muse, mutect2, varscan2
- OR14I1 | c.18A>G p.K6= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- OR2T10 | c.915G>C p.L305= | Silent (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
- OR51E1 | c.942C>T p.H314= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs549451979; called by mutect2, varscan2
- OR6P1 | c.684C>T p.I228= | Silent (SNP) | VAF 243/1371 reads (18%) | called by muse, mutect2, varscan2
- OR8B12 | c.69G>T p.R23= | Silent (SNP) | VAF 98/316 reads (31%) | catalogued as COSV60910866; called by muse, mutect2, varscan2
- OR8J1 | c.522C>T p.I174= | Silent (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2
- PAK5 | c.819G>A p.L273= | Silent (SNP) | VAF 100/470 reads (21%) | called by muse, mutect2, varscan2
- PCDH15 | c.3696G>A p.L1232= | Silent (SNP) | VAF 32/386 reads (8%) | catalogued as COSV57333717, COSV57360971; called by muse, mutect2
- PCDHB10 | c.747C>A p.T249= | Silent (SNP) | VAF 244/337 reads (72%) | called by muse, mutect2, varscan2
- PFKFB4 | c.516G>A p.V172= | Silent (SNP) | VAF 8/197 reads (4%) | catalogued as COSV51682119; called by muse, mutect2
- PHF24 | c.670C>T p.L224= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as rs756625480; called by muse, mutect2
- PKHD1L1 | c.2919A>C p.S973= | Silent (SNP) | VAF 288/415 reads (69%) | called by muse, mutect2, varscan2
- PPP1R3E | c.528G>C p.G176= | Silent (SNP) | VAF 37/302 reads (12%) | called by muse, mutect2, varscan2
- PRCP | c.991C>T p.L331= | Silent (SNP) | VAF 312/662 reads (47%) | called by muse, mutect2, varscan2
- RBMXL3 | c.1236C>A p.G412= | Silent (SNP) | VAF 109/154 reads (71%) | called by muse, mutect2, varscan2
- RELT | c.54C>A p.P18= | Silent (SNP) | VAF 231/607 reads (38%) | called by muse, mutect2, varscan2
- RET | c.3081G>C p.L1027= | Silent (SNP) | VAF 80/417 reads (19%) | called by muse, mutect2, varscan2
- RP2 | c.408C>T p.I136= | Silent (SNP) | VAF 156/505 reads (31%) | called by muse, mutect2, varscan2
- RP2 | c.621C>G p.L207= | Silent (SNP) | VAF 100/334 reads (30%) | catalogued as rs782093466; called by muse, varscan2
- RYR2 | c.8280T>C p.Y2760= | Silent (SNP) | VAF 83/228 reads (36%) | catalogued as COSV100773090; called by muse, mutect2, varscan2
- RYR2 | c.12273G>A p.A4091= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as rs966083978; ClinVar: likely benign; called by muse, mutect2
- SAG | c.1098C>T p.D366= | Silent (SNP) | VAF 115/803 reads (14%) | called by muse, mutect2, varscan2
- SAP130 | c.1377C>T p.I459= | Silent (SNP) | VAF 39/193 reads (20%) | called by muse, mutect2, varscan2
- SAPCD2 | c.489C>T p.A163= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- SBF1 | c.2544C>G p.L848= | Silent (SNP) | VAF 60/165 reads (36%) | called by muse, mutect2, varscan2
- SEC14L1 | c.267G>T p.R89= | Silent (SNP) | VAF 172/623 reads (28%) | called by muse, mutect2, varscan2
- SERPINA11 | c.1002C>T p.N334= | Silent (SNP) | VAF 82/369 reads (22%) | called by muse, mutect2, varscan2
- SLA2 | c.12G>T p.L4= | Silent (SNP) | VAF 90/392 reads (23%) | called by muse, mutect2, varscan2
- SLC35F5 | c.903A>G p.L301= | Silent (SNP) | VAF 52/215 reads (24%) | catalogued as rs369440698; called by muse, mutect2, varscan2
- SLC39A12 | c.585G>C p.V195= | Silent (SNP) | VAF 272/727 reads (37%) | called by muse, mutect2, varscan2
- SLIT1 | c.3057C>T p.V1019= | Silent (SNP) | VAF 95/491 reads (19%) | called by muse, mutect2, varscan2
- SLITRK4 | c.220C>T p.L74= | Silent (SNP) | VAF 117/143 reads (82%) | catalogued as COSV100567133; called by muse, mutect2, varscan2
- SPATA7 | c.1602G>T p.R534= | Silent (SNP) | VAF 44/231 reads (19%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.666G>A p.Q222= | Silent (SNP) | VAF 55/256 reads (21%) | catalogued as rs990677874; called by muse, mutect2, varscan2
- SYNE2 | c.6654C>T p.F2218= | Silent (SNP) | VAF 71/548 reads (13%) | catalogued as COSV59939017; called by muse, mutect2, varscan2
- SYNPO2 | c.2625C>G p.L875= | Silent (SNP) | VAF 239/379 reads (63%) | called by muse, mutect2, varscan2
- SYNRG | c.3927C>G p.V1309= | Silent (SNP) | VAF 196/424 reads (46%) | called by muse, mutect2, varscan2
- TARM1 | c.258C>A p.G86= (on ENST00000616041 / NM_001330650.1; = p.G78= on NM_001135686.3) | Silent (SNP) | VAF 391/603 reads (65%) | catalogued as COSV101444637, COSV71524728; called by muse, mutect2, varscan2
- TBC1D3F | c.309C>G p.P103= | Silent (SNP) | VAF 47/190 reads (25%) | called by mutect2, varscan2
- TEX11 | c.996C>T p.D332= (on ENST00000344304; = p.D317= on NM_031276.3) | Silent (SNP) | VAF 194/258 reads (75%) | called by muse, mutect2, varscan2
- TEX12 | c.279C>T p.F93= | Silent (SNP) | VAF 24/201 reads (12%) | called by muse, mutect2, varscan2
- TEX29 | c.162G>C p.A54= | Silent (SNP) | VAF 132/466 reads (28%) | catalogued as COSV52095648; called by muse, mutect2, varscan2
- TIAM1 | c.1602G>A p.E534= | Silent (SNP) | VAF 90/348 reads (26%) | catalogued as rs772731077, COSV54541033; called by muse, mutect2, varscan2
- TMCC2 | c.1212G>A p.E404= | Silent (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- TRIO | c.7005G>A p.R2335= | Silent (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- TTN | c.4083C>T p.I1361= (on ENST00000591111; = p.I1315= on NM_003319.4) | Silent (SNP) | VAF 147/813 reads (18%) | called by muse, mutect2, varscan2
- UBC | c.270C>G p.T90= | Silent (SNP) | VAF 207/837 reads (25%) | called by muse, mutect2, varscan2
- WRN | c.2265C>T p.V755= | Silent (SNP) | VAF 133/345 reads (39%) | catalogued as COSV53298784; called by muse, mutect2, varscan2
- XKRX | c.447G>C p.L149= | Silent (SNP) | VAF 230/612 reads (38%) | catalogued as COSV100139750; called by muse, mutect2, varscan2
- ZMYM6 | c.363C>T p.I121= | Silent (SNP) | VAF 243/898 reads (27%) | called by muse, mutect2, varscan2
- ZNF250 | c.1605T>C p.Y535= | Silent (SNP) | VAF 158/232 reads (68%) | called by muse, mutect2, varscan2
- ZNF469 | c.7248C>T p.L2416= (on ENST00000437464; = p.L2444= on NM_001367624.2) | Silent (SNP) | VAF 158/509 reads (31%) | called by muse, mutect2, varscan2
- ZNF487 | c.151C>T p.L51= | Silent (SNP) | VAF 241/511 reads (47%) | called by muse, mutect2, varscan2
- ZNF544 | c.1188C>T p.V396= | Silent (SNP) | VAF 11/297 reads (4%) | catalogued as rs1457902315; called by muse, mutect2
- ZNF835 | c.579G>A p.P193= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV73379462; called by muse, mutect2, varscan2
- ZYG11B | c.1024C>A p.R342= | Silent (SNP) | VAF 118/896 reads (13%) | catalogued as rs1558131291; called by muse, varscan2
- AC011330.1 | n.979C>G | RNA (SNP) | VAF 68/269 reads (25%) | called by mutect2, varscan2
- AL391261.1 | n.277G>T | RNA (SNP) | VAF 107/602 reads (18%) | called by muse, varscan2
- AL391261.1 | n.276G>T | RNA (SNP) | VAF 108/606 reads (18%) | called by muse, varscan2
- AMN | c.1006+37C>A | Intron (SNP) | VAF 25/113 reads (22%) | called by muse, varscan2
- BRCA1 | c.*842G>C | 3'UTR (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- C11orf40 | n.256G>T | RNA (SNP) | VAF 253/372 reads (68%) | called by muse, mutect2, varscan2
- CA5BP1 | n.429C>T | RNA (SNP) | VAF 65/281 reads (23%) | called by muse, mutect2, varscan2
- CALCA | chr11:14967897 G>A | 3'Flank (SNP) | VAF 174/372 reads (47%) | called by muse, mutect2, varscan2
- CASP12 | c.260-468G>A | Intron (SNP) | VAF 153/460 reads (33%) | called by muse, mutect2, varscan2
- CCDC162P | n.6157G>C | RNA (SNP) | VAF 118/259 reads (46%) | called by muse, mutect2, varscan2
- CENPH | c.*4G>A | 3'UTR (SNP) | VAF 66/414 reads (16%) | catalogued as COSV99295441; called by muse, mutect2, varscan2
- CFAP53 | c.-15G>A | 5'UTR (SNP) | VAF 75/366 reads (20%) | catalogued as COSV99495963; called by muse, varscan2
- CHD5 | c.*40A>T | 3'UTR (SNP) | VAF 127/337 reads (38%) | called by muse, mutect2, varscan2
- CSNK1G2 | c.682+17C>T | Intron (SNP) | VAF 51/64 reads (80%) | catalogued as rs1340146200; called by muse, mutect2, varscan2
- CYP3A5 | c.72-322T>A | Intron (SNP) | VAF 301/795 reads (38%) | called by muse, mutect2, varscan2
- CYP4F24P | n.570C>A | RNA (SNP) | VAF 370/470 reads (79%) | called by muse, mutect2, varscan2
- DCC | c.-18G>A | 5'UTR (SNP) | VAF 132/975 reads (14%) | catalogued as rs748787755, COSV71438149; called by muse, mutect2, varscan2
- DECR2 | c.149+604A>G | Intron (SNP) | VAF 144/193 reads (75%) | called by muse, mutect2, varscan2
- DMAC2L | chr14:50332132 T>C | 3'Flank (SNP) | VAF 112/849 reads (13%) | catalogued as rs775635854; called by muse, mutect2, varscan2
- DST | c.4297-2377C>A | Intron (SNP) | VAF 126/294 reads (43%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.5978-9C>G | Intron (SNP) | VAF 46/715 reads (6%) | called by muse, mutect2
- FRMD8 | c.85+103C>T | Intron (SNP) | VAF 103/655 reads (16%) | called by muse, mutect2, varscan2
- FRMPD2B | n.718T>A | RNA (SNP) | VAF 186/759 reads (25%) | called by muse, mutect2, varscan2
- FSHB | c.*17C>G | 3'UTR (SNP) | VAF 104/589 reads (18%) | called by muse, mutect2, varscan2
- GUSBP10 | n.612C>G | RNA (SNP) | VAF 286/827 reads (35%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457870 G>T | 5'Flank (SNP) | VAF 121/904 reads (13%) | called by muse, mutect2, varscan2
- HOXA2 | c.391+158G>T | Intron (SNP) | VAF 84/217 reads (39%) | called by muse, mutect2, varscan2
- IDE | c.-50G>A | 5'UTR (SNP) | VAF 62/258 reads (24%) | called by muse, mutect2, varscan2
- ITK | c.496-9C>G | Intron (SNP) | VAF 113/447 reads (25%) | called by muse, mutect2, varscan2
- JMJD1C | c.-96C>G | 5'UTR (SNP) | VAF 116/300 reads (39%) | catalogued as rs768927664; called by muse, mutect2, varscan2
- KCNK16 | c.803-88C>G | Intron (SNP) | VAF 154/906 reads (17%) | catalogued as COSV64677753; called by muse, varscan2
- KHDRBS2 | c.-37C>A | 5'UTR (SNP) | VAF 78/274 reads (28%) | called by muse, varscan2
- KLF6 | c.*3033_*3034del | 3'UTR (DEL) | VAF 93/549 reads (17%) | called by mutect2, pindel, varscan2
- LINC01551 | n.1254+18471G>T | Intron (SNP) | VAF 34/66 reads (52%) | called by muse, varscan2
- LIPE | c.883+1598G>T | Intron (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- MCEE | c.*29G>T | 3'UTR (SNP) | VAF 257/575 reads (45%) | called by muse, mutect2, varscan2
- MECOM | chr3:169149709 T>A | 5'Flank (SNP) | VAF 50/283 reads (18%) | called by muse, mutect2, varscan2
- MGAM | c.4619-8688G>A | Intron (SNP) | VAF 88/747 reads (12%) | called by muse, mutect2, varscan2
- MSRB2 | c.-29G>C | 5'UTR (SNP) | VAF 41/295 reads (14%) | called by muse, mutect2, varscan2
- NBAS | c.1084-5053A>T | Intron (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- NCF1B | n.159-1378C>T | Intron (SNP) | VAF 163/1996 reads (8%) | called by muse, mutect2
- NECTIN3-AS1 | n.1172+81G>A | Intron (SNP) | VAF 53/316 reads (17%) | called by muse, mutect2, varscan2
- NEU4 | chr2:241809198 C>A | 5'Flank (SNP) | VAF 91/474 reads (19%) | called by muse, mutect2, varscan2
- NR1I3 | c.238+15T>C | Intron (SNP) | VAF 178/479 reads (37%) | catalogued as rs1313422195; called by muse, mutect2, varscan2
- NRK | c.-49C>G | 5'UTR (SNP) | VAF 72/278 reads (26%) | catalogued as rs767952703, COSV99688113; called by muse, mutect2, varscan2
- POLR3B | c.2985-1220C>T | Intron (SNP) | VAF 143/381 reads (38%) | called by muse, mutect2, varscan2
- PSG5 | c.-1C>A | 5'UTR (SNP) | VAF 76/163 reads (47%) | called by muse, varscan2
- PSMG3-AS1 | n.3818C>T | RNA (SNP) | VAF 181/422 reads (43%) | catalogued as rs1461107960; called by muse, mutect2, varscan2
- PTPRQ | c.19+1125A>G | Intron (SNP) | VAF 138/203 reads (68%) | catalogued as COSV73428327; called by muse, mutect2, varscan2
- RHBG | c.188-2598C>T | Intron (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159665 G>T | 5'Flank (SNP) | VAF 35/54 reads (65%) | called by muse, mutect2, varscan2
- RPS8 | c.387+75C>T | Intron (SNP) | VAF 53/357 reads (15%) | called by muse, mutect2, varscan2
- SLC9B2 | c.*112A>T | 3'UTR (SNP) | VAF 152/211 reads (72%) | called by muse, mutect2, varscan2
- SRRM2 | c.-104G>C | 5'UTR (SNP) | VAF 57/288 reads (20%) | catalogued as rs916275928; called by muse, mutect2, varscan2
- STK17A | c.-71G>A | 5'UTR (SNP) | VAF 44/391 reads (11%) | catalogued as rs987087054; called by muse, mutect2, varscan2
- STMP1 | c.-6G>A | 5'UTR (SNP) | VAF 82/422 reads (19%) | called by muse, mutect2, varscan2
- TG | c.7239+29062C>A | Intron (SNP) | VAF 429/669 reads (64%) | called by muse, mutect2, varscan2
- TTN | c.10361-5343G>T | Intron (SNP) | VAF 48/189 reads (25%) | called by muse, mutect2, varscan2
- UBXN1 | c.290+35G>A | Intron (SNP) | VAF 131/516 reads (25%) | called by muse, mutect2, varscan2
- UGP2 | c.-22A>T | 5'UTR (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- XPO1 | c.1385-41C>G | Intron (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2
- ZFYVE26 | c.7416+23G>C | Intron (SNP) | VAF 444/1007 reads (44%) | catalogued as COSV100720130; called by muse, mutect2, varscan2
- ZNF236 | c.4589-1109G>C | Intron (SNP) | VAF 135/894 reads (15%) | called by muse, mutect2, varscan2
- ZSCAN16 | chr6:28123135 G>C | 5'Flank (SNP) | VAF 111/160 reads (69%) | called by muse, mutect2, varscan2
